Somatic mutation profile of tumor specimen TARGET-30-PATFCY-01A (aliquot TARGET-30-PATFCY-01A-01D) from TARGET case TARGET-30-PATFCY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,040 days).
Specimen TARGET-30-PATFCY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b336f72-eac3-4751-b84e-aae3b2527909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATFCY-10A (Blood Derived Normal), aliquot TARGET-30-PATFCY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e402dba-0397-4922-9731-757869fe5d2c

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3718T>G p.L1240V | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs863225282, COSV66566889; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMP1 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV56819785; called by muse, mutect2, varscan2
- DSCAML1 | c.1543C>T p.R515C (on ENST00000321322; = p.R455C on NM_020693.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201713277; called by muse, mutect2, varscan2
- FAM170A | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV58925015, COSV58926555; called by muse, mutect2, varscan2
- IMPA2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988651206, COSV52319551; called by muse, mutect2, varscan2
- OR1A2 | c.646T>A p.S216T | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67936205, COSV67936378; called by muse, mutect2, varscan2
- PDE8B | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1188350862, COSV53737132; called by muse, mutect2, varscan2
- PTPRH | c.2529G>T p.E843D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV54745080; called by muse, mutect2, varscan2
- SLAIN2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.495); catalogued as rs771379848, COSV51906254; called by muse, mutect2, varscan2
- SLC22A10 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100235972, COSV60421190, COSV60421696; called by muse, mutect2, varscan2
- USP6 | c.2308T>G p.S770A | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.097); catalogued as COSV51481728; called by muse, mutect2, varscan2
- ZNF277 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV62464145; called by muse, mutect2, varscan2
- AIFM2 | c.1062C>T p.T354= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57159174; called by muse, mutect2, varscan2
- FZD3 | c.804C>A p.I268= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV53535335; called by muse, mutect2, varscan2
- KIR3DL3 | c.342G>T p.V114= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- ZZEF1 | c.4386A>G p.T1462= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
